Somatic mutation profile of tumor specimen MP2PRT-PATBCY-TMP1-A (aliquot MP2PRT-PATBCY-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATBCY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (991 days).
Specimen MP2PRT-PATBCY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2993f99-48d0-45b1-9230-099402d53627.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBCY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBCY-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cac32a03-4b26-4bf6-a05e-404464984791

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT4 | c.4942G>A p.V1648M | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749029819; called by muse, mutect2
- KIF21B | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 47/693 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs371947852; called by muse, mutect2
- PRTG | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 10/309 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101221514; called by muse, mutect2
- SLC8A2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 101/540 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs746692355, COSV52639635; called by muse, mutect2, varscan2
- DNM2 | c.1997T>A p.I666N (on ENST00000355667 / NM_001005360.3; = p.I662N on NM_004945.3) | Missense Mutation (SNP) | VAF 20/433 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FAM161B | c.482C>G p.S161C (on ENST00000651776; = p.S98C on NM_152445.3) | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PTCHD3 | c.726G>A p.A242= | Silent (SNP) | VAF 234/571 reads (41%) | catalogued as rs768736791, COSV71256499; called by muse, mutect2, varscan2
- TMEM132C | c.2055C>T p.N685= | Silent (SNP) | VAF 87/362 reads (24%) | catalogued as rs1377355923, COSV100175549, COSV59415675; called by muse, mutect2, varscan2
- TOX3 | c.1011C>A p.A337= | Silent (SNP) | VAF 16/246 reads (7%) | catalogued as COSV99568279; called by muse, mutect2
- IGHV1-58 | chr14:106627248 ins GGGGGGATCCA | 5'Flank (INS) | VAF 34/155 reads (22%) | called by pindel, varscan2
- IGHV3-7 | chr14:106062150 ins G | 3'Flank (INS) | VAF 18/144 reads (13%) | called by mutect2, pindel*, varscan2*
